Somatic mutation profile of tumor specimen TCGA-B6-A0IB-01A (aliquot TCGA-B6-A0IB-01A-11W-A050-09) from TCGA case TCGA-B6-A0IB, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 64.7 years (23,646 days).
Specimen TCGA-B6-A0IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89811533-3674-4144-8be1-dabb7fa5f84d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IB-10A (Blood Derived Normal), aliquot TCGA-B6-A0IB-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa8a3c5f-615f-4053-a308-0da3d065f639

The open-access MAF lists 72 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.5317G>T p.E1773* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs1114167291, COSV56371394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.493-2A>G p.X165_splice | Splice Site (SNP) | VAF 44/72 reads (61%) | catalogued as rs587781784, CS075218, COSV64297091, COSV64308401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASIC3 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV52506817, COSV99874856; called by muse, mutect2
- ATP1A1 | c.1553G>A p.C518Y | Missense Mutation (SNP) | VAF 80/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55194188; called by muse, mutect2, varscan2
- BMP15 | c.328+1G>A p.X110_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as rs1557279953, COSV53141937; called by muse, mutect2
- CACNG2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs1186080531, COSV55640751; called by muse, mutect2, varscan2
- CDC42BPA | c.4975C>T p.R1659W (on ENST00000334218 / NM_001366019.2; = p.R1646W on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs532891873, COSV62002587; called by muse, mutect2, varscan2
- CETP | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs984216604, COSV52364286; called by muse, mutect2, varscan2
- CSAD | c.616G>C p.D206H (on ENST00000444623 / NM_001244705.2; = p.D233H on NM_015989.5) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99914960; called by muse, mutect2
- CUX1 | c.319C>T p.R107C (on ENST00000292535 / NM_181552.4; = p.R118C on NM_001913.5) | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782680467, COSV99472733; called by muse, mutect2
- DNAH8 | c.8230G>A p.E2744K | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59478725; called by muse, mutect2, varscan2
- DPP4 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1355424702, COSV62105067; called by muse, mutect2, varscan2
- ENSA | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55027466; called by muse, mutect2, varscan2
- EP300 | c.4384C>T p.R1462* | Nonsense Mutation (SNP) | VAF 8/136 reads (6%) | catalogued as COSV54332184; called by muse, mutect2
- FGG | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV60196811; called by muse, mutect2, varscan2
- G6PD | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs782690505, COSV63704362; called by muse, mutect2, varscan2
- GAB4 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV68755167; called by muse, mutect2, varscan2
- GPNMB | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99326756; called by muse, mutect2
- GPRASP2 | c.2149G>T p.A717S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.204); catalogued as COSV59992433; called by muse, mutect2, varscan2
- GRK1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs374698122; called by muse, mutect2, varscan2
- H2AZ1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV56455919; called by muse, mutect2, varscan2
- HIBCH | c.1149T>G p.D383E | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV61410817; called by muse, mutect2, varscan2
- HNF4A | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 102/274 reads (37%) | catalogued as COSV100291666; called by muse, mutect2
- HNRNPUL1 | c.2297G>C p.G766A | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV54191632; called by muse, mutect2, varscan2
- LMBRD1 | c.752G>A p.S251N (on ENST00000649011; = p.S229N on NM_018368.4) | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV65299966; called by muse, mutect2, varscan2
- MPRIP | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100506081; called by muse, mutect2
- MXD4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.425); catalogued as rs774792731, COSV61467086; called by muse, varscan2
- NCOA7 | c.665T>A p.L222* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99997522; called by muse, mutect2, varscan2
- NF1 | c.5680G>C p.E1894Q (on ENST00000358273 / NM_001042492.3; = p.E1873Q on NM_000267.3) | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs774893767, COSV62209458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.962A>G p.K321R (on ENST00000339876 / NM_001378329.1; = p.K332R on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58379349; called by muse, mutect2, varscan2
- NLRP1 | c.4372G>T p.E1458* (on ENST00000572272 / NM_033004.4; = p.E1414* on NM_014922.5) | Nonsense Mutation (SNP) | VAF 40/164 reads (24%) | catalogued as COSV52578221; called by muse, varscan2
- P2RY2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100232836; called by mutect2, varscan2
- PC | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436643226, COSV63082041; ClinVar: uncertain significance; called by muse, mutect2
- PCLO | c.15410G>T p.S5137I | Missense Mutation (SNP) | VAF 35/688 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100436500; called by muse, mutect2
- PER3 | c.40del p.A14Lfs*49 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as rs762552158; called by mutect2, varscan2
- PHLDB3 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1453542560, COSV104391504, COSV52672158; called by muse, mutect2, varscan2
- POLR3F | c.810del p.Y270* | Frame Shift Del (DEL) | VAF 52/171 reads (30%) | catalogued as COSV61500301; called by mutect2, pindel, varscan2
- PRKG1 | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as COSV100909178; called by muse, mutect2, varscan2
- PROX1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54783394; called by muse, mutect2, varscan2
- PTK7 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1340122702, COSV57851528; called by muse, varscan2
- RAB3C | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51442059; called by muse, mutect2, varscan2
- RSL1D1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1475884724, COSV100852005, COSV63078487; called by muse, mutect2, varscan2
- RTL9 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV71826356; called by muse, mutect2, varscan2
- SLC9A3R1 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52854950; called by muse, mutect2, varscan2
- SLCO1A2 | c.1561A>G p.S521G | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as COSV56610131; called by muse, mutect2, varscan2
- SLF1 | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV54373449; called by muse, mutect2, varscan2
- SNAPIN | c.242A>G p.Y81C | Missense Mutation (SNP) | VAF 14/403 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100721999; called by muse, mutect2
- TIPARP | c.443G>T p.S148I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.058); catalogued as COSV99903951; called by muse, mutect2
- TMEM130 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 51/1326 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs756989914, COSV59560100; called by muse, mutect2
- TMTC3 | c.2668A>G p.I890V | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); catalogued as rs1238686218, COSV57126244; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV99162912; called by muse, mutect2
- UBA7 | c.1760C>T p.S587L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV61093507; called by muse, mutect2, varscan2
- ZBTB18 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV62398345; called by muse, mutect2, varscan2
- ZC2HC1C | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV53173231; called by muse, mutect2, varscan2
- MAP2K4 | c.218+2dup p.X73_splice | Splice Site (INS) | VAF 91/157 reads (58%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.228_240del p.P77Rfs*67 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, varscan2
- ABCA13 | c.14346T>A p.T4782= | Silent (SNP) | VAF 36/354 reads (10%) | catalogued as COSV68950549; called by muse, mutect2
- ABCB1 | c.1803C>T p.F601= | Silent (SNP) | VAF 30/195 reads (15%) | catalogued as rs147451192, COSV55962933; called by muse, mutect2, varscan2
- ARHGEF11 | c.3696C>T p.D1232= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as rs372348613; called by muse, mutect2
- CEACAM18 | c.573C>G p.V191= | Silent (SNP) | VAF 21/162 reads (13%) | catalogued as COSV67284034; called by muse, mutect2, varscan2
- FGD6 | c.2454C>G p.S818= | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as COSV100676760, COSV59697749; called by muse, mutect2
- NAV2 | c.2037G>A p.Q679= (on ENST00000396087 / NM_001244963.2; = p.Q656= on NM_145117.5) | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV100586838; called by muse, mutect2
- NEGR1 | c.918C>G p.T306= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV100165378; called by muse, mutect2
- NIPAL4 | c.972G>A p.P324= | Silent (SNP) | VAF 55/150 reads (37%) | catalogued as rs368885385; called by muse, mutect2, varscan2
- NKX2-5 | c.457C>T p.L153= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- OR51Q1 | c.81C>A p.I27= | Silent (SNP) | VAF 52/359 reads (14%) | catalogued as COSV56180539; called by muse, mutect2, varscan2
- PCYOX1 | c.930C>T p.I310= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs781327432, COSV52478123; called by muse, mutect2, varscan2
- PLOD3 | c.1464C>T p.D488= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV56185740; called by muse, mutect2, varscan2
- SEMA3B | c.462C>T p.L154= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV100312915; called by muse, mutect2, varscan2
- SP4 | c.1824G>A p.Q608= | Silent (SNP) | VAF 50/520 reads (10%) | catalogued as COSV99754912; called by muse, mutect2
- ZCCHC2 | c.2943G>A p.A981= | Silent (SNP) | VAF 49/193 reads (25%) | catalogued as rs369047194; called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516159 C>G | 5'Flank (SNP) | VAF 6/28 reads (21%) | catalogued as rs1310173811, COSV99389225; called by muse, mutect2
